Somatic mutation profile of tumor specimen TCGA-XF-AAMQ-01A (aliquot TCGA-XF-AAMQ-01A-11D-A42E-08) from TCGA case TCGA-XF-AAMQ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 59.3 years (21,660 days).
Specimen TCGA-XF-AAMQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 328165fe-c56c-45e1-a456-3d012781b847.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-AAMQ-10A (Blood Derived Normal), aliquot TCGA-XF-AAMQ-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4490c401-aae5-4c91-819b-7ab8a30fabd8

The open-access MAF lists 231 somatic variants for this specimen: 160 protein-altering or splice-affecting, 63 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 137, Silent 63, Nonsense Mutation 18, RNA 4, Frame Shift Del 2, Intron 2, Frame Shift Ins 1, Splice Site 1, 5'UTR 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NKX2-5 | c.701C>A p.S234* | Nonsense Mutation (SNP) | VAF 6/12 reads (50%) | catalogued as rs773922431, COSV100234913; ClinVar: likely pathogenic; called by muse, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 10/17 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2
- ABCA13 | c.2631C>A p.F877L | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV70034113, COSV70041798; called by muse, mutect2, varscan2
- ACAP3 | c.1017G>C p.K339N | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV100686608, COSV61223268; called by muse, mutect2, varscan2
- ADCY4 | c.3088G>A p.E1030K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as rs1485975390, COSV60256976; called by muse, mutect2, varscan2
- AGL | c.1015C>A p.P339T | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.342); catalogued as COSV54057355; called by muse, mutect2, varscan2
- AGPS | c.1672C>T p.Q558* | Nonsense Mutation (SNP) | VAF 45/56 reads (80%) | catalogued as COSV99931743; called by muse, mutect2, varscan2
- AGTR1 | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.07); catalogued as rs377193123; called by muse, mutect2, varscan2
- ALKBH5 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 36/57 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as COSV52763795; called by muse, mutect2, varscan2
- ALMS1 | c.6196G>C p.D2066H | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT tolerated (0.74); PolyPhen benign (0.03); catalogued as rs1312217916, COSV52502350, COSV52519674; called by muse, mutect2, varscan2
- ANKDD1A | c.1196C>T p.S399F | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as rs1233661184, COSV63088825; called by muse, mutect2, varscan2
- APEX1 | c.491C>T p.S164L | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as rs778999137, COSV51658617; called by muse, mutect2, varscan2
- ARCN1 | c.838G>C p.E280Q | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50616933; called by muse, mutect2, varscan2
- ARFGEF2 | c.4069G>C p.E1357Q | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV64213331; called by muse, mutect2, varscan2
- ARMT1 | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 49/61 reads (80%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs35734927; called by muse, mutect2, varscan2
- ARSG | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as rs1298344479, COSV71593876; called by muse, mutect2, varscan2
- ATP1B2 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as rs997568142, COSV100006817, COSV51516476; called by muse, mutect2, varscan2
- BDP1 | c.5620G>A p.E1874K | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1163936072, COSV62433979; called by muse, mutect2, varscan2
- BRAF | c.2113-1G>T p.X705_splice (on ENST00000288602 / NM_001374244.1; = p.X665_splice on NM_004333.6 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 14/38 reads (37%) | catalogued as COSV56338402; called by muse, mutect2, varscan2
- C1QL1 | c.696C>G p.I232M | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53647502; called by muse, mutect2, varscan2
- C8orf74 | c.769C>G p.L257V | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as COSV58755291; called by muse, mutect2, varscan2
- CADM2 | c.667A>C p.I223L (on ENST00000407528 / NM_001167674.2; = p.I225L on NM_153184.4) | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV67398676; called by muse, mutect2, varscan2
- CAMK2B | c.1382C>T p.S461L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV51665268; called by muse, mutect2, varscan2
- CATSPERB | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV56433087; called by muse, mutect2, varscan2
- CCDC151 | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.246); catalogued as COSV62697419, COSV62698943; called by muse, mutect2, varscan2
- CCDC24 | c.160C>G p.R54G | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.437); catalogued as rs1162877305, COSV58845742; called by muse, mutect2, varscan2
- CCDC40 | c.3409G>C p.E1137Q | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV56411378; called by muse, mutect2, varscan2
- CDC45 | c.489G>A p.E163= | Splice Region (SNP) | VAF 10/27 reads (37%) | catalogued as COSV54247957; called by muse, mutect2, varscan2
- CDH2 | c.630C>A p.F210L | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV52293339; called by muse, mutect2, varscan2
- CENPF | c.1484C>G p.S495C | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.099); catalogued as COSV65278394; called by muse, mutect2, varscan2
- CHD5 | c.2332G>A p.V778I | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.983); catalogued as COSV52423005; called by muse, mutect2, varscan2
- CHRNA5 | c.1128G>C p.Q376H | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV55140192; called by muse, mutect2, varscan2
- CHSY1 | c.1076C>A p.P359H | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as COSV54255566; called by muse, mutect2, varscan2
- CKMT2 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as rs1063543, COSV54174707; called by muse, mutect2, varscan2
- CLCN1 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as COSV100578117, COSV58373701; called by muse, mutect2, varscan2
- CNGA3 | c.1861G>A p.A621T | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as rs546831778, COSV55624691; called by muse, mutect2, varscan2
- CNTROB | c.1534G>C p.E512Q | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.528); catalogued as COSV66609198; called by muse, mutect2, varscan2
- CORO1A | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV54631957; called by muse, mutect2, varscan2
- CPT2 | c.1766C>T p.T589M | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756414686, COSV53760170; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSMD3 | c.7598C>T p.S2533L (on ENST00000297405 / NM_001363185.1; = p.S2429L on NM_052900.3) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.665); catalogued as COSV52290389; called by muse, mutect2, varscan2
- CSMD3 | c.6838G>A p.E2280K (on ENST00000297405 / NM_001363185.1; = p.E2176K on NM_052900.3) | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.141); catalogued as rs1416124406, COSV52270769; called by muse, mutect2, varscan2
- CSNK2A1 | c.799C>G p.P267A | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as COSV53937176; called by muse, mutect2, varscan2
- CXorf66 | c.853G>C p.D285H | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.201); catalogued as COSV100983937, COSV65169516, COSV65169699; called by muse, mutect2, varscan2
- CYP11B2 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV59997476; called by muse, mutect2, varscan2
- CYP27C1 | c.1023C>G p.I341M | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); catalogued as rs1414679479, COSV58867709, COSV58867986; called by muse, mutect2, varscan2
- DOP1B | c.6787G>A p.D2263N | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV67690879; called by muse, mutect2, varscan2
- EDC4 | c.3066G>C p.Q1022H | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1338359083, COSV59303636; called by muse, mutect2, varscan2
- F7 | c.348G>C p.Q116H | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV60647635; called by muse, mutect2, varscan2
- FAM83H | c.2794G>C p.E932Q | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.454); catalogued as COSV62029821; called by muse, mutect2, varscan2
- FAT1 | c.10893C>G p.I3631M | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV101498602, COSV71673784; called by muse, mutect2, varscan2
- FBXO11 | c.788G>A p.R263K (on ENST00000403359 / NM_001190274.2; = p.R179K on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/37 reads (78%) | SIFT tolerated (0.15); PolyPhen benign (0.116); catalogued as COSV57025108; called by muse, mutect2, varscan2
- FNIP1 | c.3239C>T p.S1080F | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100330453, COSV57199728; called by muse, mutect2, varscan2
- FOXQ1 | c.581G>A p.W194* | Nonsense Mutation (SNP) | VAF 30/41 reads (73%) | catalogued as COSV99723353; called by muse, mutect2, varscan2
- GABRR1 | c.1321C>G p.Q441E | Missense Mutation (SNP) | VAF 49/58 reads (84%) | SIFT tolerated (0.75); PolyPhen benign (0.021); catalogued as COSV65620375; called by muse, mutect2, varscan2
- GHRHR | c.801C>G p.F267L | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV58196515, COSV58197834; called by muse, mutect2, varscan2
- GOLGB1 | c.2386G>A p.E796K | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61469896; called by muse, mutect2, varscan2
- GPSM2 | c.1058G>A p.R353K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs145339242; called by muse, mutect2, varscan2
- GRAMD1B | c.952G>C p.E318Q | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV59209558; called by muse, mutect2, varscan2
- GRID2 | c.2098G>C p.E700Q | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV56253148; called by muse, mutect2, varscan2
- GRK1 | c.940G>A p.V314I | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs374722973; called by muse, mutect2, varscan2
- GYS2 | c.673G>C p.D225H | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.863); catalogued as rs1470172143, COSV53927666; called by muse, mutect2, varscan2
- HAUS6 | c.1834C>G p.Q612E | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.27); PolyPhen benign (0.199); catalogued as rs769268526, COSV100997912; called by muse, mutect2, varscan2
- HDAC1 | c.826C>A p.L276I | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV61482329; called by muse, mutect2, varscan2
- HSPG2 | c.11015C>G p.S3672C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1266802915, COSV65933925; called by muse, mutect2, varscan2
- IGFBP1 | c.574G>C p.E192Q | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV51875279; called by muse, mutect2, varscan2
- IL22RA1 | c.1429G>A p.D477N | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as COSV54630055; called by muse, mutect2, varscan2
- JMY | c.2309C>G p.S770* | Nonsense Mutation (SNP) | VAF 19/81 reads (23%) | catalogued as COSV101268123; called by muse, mutect2, varscan2
- KASH5 | c.1285G>C p.E429Q | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.082); catalogued as rs1223779658, COSV71358383; called by muse, mutect2, varscan2
- KHDC4 | c.1081C>T p.Q361* | Nonsense Mutation (SNP) | VAF 27/77 reads (35%) | catalogued as COSV100850857; called by muse, mutect2, varscan2
- KIF12 | c.1137G>C p.Q379H (on ENST00000640217; = p.Q241H on NM_138424.1) | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV65118003; called by muse, mutect2, varscan2
- KRT20 | c.403C>G p.Q135E | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.423); catalogued as COSV51425958; called by muse, mutect2, varscan2
- KRT38 | c.896C>A p.S299Y | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55847327; called by muse, mutect2, varscan2
- KSR2 | c.2688G>C p.Q896H | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.511); catalogued as COSV56681417; called by muse, mutect2, varscan2
- LONRF3 | c.2026C>T p.Q676* (on ENST00000371628 / NM_001031855.3; = p.Q635* on NM_024778.5) | Nonsense Mutation (SNP) | VAF 54/168 reads (32%) | catalogued as COSV100504691; called by muse, mutect2, varscan2
- LRRC6 | c.281A>G p.D94G | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51546683; called by muse, mutect2, varscan2
- LRRK2 | c.2314C>T p.R772* | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | catalogued as rs376015112; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAD2L1BP | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 73/84 reads (87%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.657); catalogued as COSV64679518; called by muse, mutect2, varscan2
- MBLAC1 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1177843032, COSV53543195; called by muse, mutect2, varscan2
- MCF2L2 | c.1891G>A p.E631K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61059963; called by muse, mutect2, varscan2
- MPEG1 | c.445C>T p.R149* | Nonsense Mutation (SNP) | VAF 15/56 reads (27%) | catalogued as rs199971720, COSV57089324; called by muse, mutect2, varscan2
- MTFR1L | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.992); catalogued as COSV65353312; called by muse, mutect2, varscan2
- MTMR11 | c.1472C>G p.S491C (on ENST00000439741 / NM_001145862.2; = p.S419C on NM_181873.3) | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.326); catalogued as COSV54966673; called by muse, mutect2, varscan2
- MYH7B | c.3973C>T p.R1325C | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as rs926249951, COSV52683575; called by muse, mutect2, varscan2
- MYO5A | c.490G>C p.E164Q | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62563752; called by muse, mutect2, varscan2
- NAB1 | c.844C>T p.Q282* | Nonsense Mutation (SNP) | VAF 59/80 reads (74%) | catalogued as COSV100493168; called by muse, mutect2, varscan2
- NCOA6 | c.3724G>C p.E1242Q | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62867117; called by muse, mutect2, varscan2
- NIPBL | c.7825G>A p.E2609K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV56962639; called by muse, mutect2, varscan2
- NODAL | c.941C>T p.A314V | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.85); PolyPhen benign (0.04); catalogued as COSV54662416; called by muse, mutect2, varscan2
- OMA1 | c.1406C>G p.S469C | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.846); catalogued as COSV62256660; called by muse, mutect2, varscan2
- OPCML | c.428C>G p.S143* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | catalogued as COSV59459734; called by muse, mutect2, varscan2
- OR2T27 | c.429G>T p.L143F | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.072); catalogued as COSV61283323; called by muse, mutect2, varscan2
- OR4M1 | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs767449153, COSV60061774; called by muse, mutect2, varscan2
- OR52E8 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV66205721; called by muse, varscan2
- OR6F1 | c.919G>A p.G307R | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV57469171; called by muse, mutect2, varscan2
- OR6Y1 | c.847T>C p.Y283H | Missense Mutation (SNP) | VAF 64/125 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56931146; called by muse, mutect2, varscan2
- OR8H1 | c.385C>G p.L129V | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57295582; called by muse, mutect2, varscan2
- PDE4B | c.501del p.P168Lfs*12 | Frame Shift Del (DEL) | VAF 64/166 reads (39%) | catalogued as COSV58491975; called by mutect2, varscan2
- PDE4B | c.502C>G p.P168A | Missense Mutation (SNP) | VAF 66/166 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV58491989; called by mutect2, varscan2
- PENK | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767796107, COSV59240443; called by muse, varscan2
- PGM5 | c.1148G>C p.S383T | Missense Mutation (SNP) | VAF 41/53 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV67163907, COSV67164856; called by muse, mutect2, varscan2
- PHKA1 | c.602C>G p.S201* | Nonsense Mutation (SNP) | VAF 25/64 reads (39%) | catalogued as COSV100262820, COSV100263933; called by muse, mutect2, varscan2
- PHYHIPL | c.348G>C p.M116I | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.884); catalogued as rs1306300335, COSV65849901; called by muse, varscan2
- PIK3C2B | c.416C>G p.S139C | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.541); catalogued as COSV65804077; called by muse, mutect2, varscan2
- PPARD | c.459G>C p.K153N | Missense Mutation (SNP) | VAF 36/44 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV61101214; called by muse, mutect2, varscan2
- PPP4R3A | c.2035G>C p.E679Q (on ENST00000554943 / NM_001366432.1; = p.E666Q on NM_001284280.1) | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV61506198; called by muse, mutect2, varscan2
- PRDM15 | c.1249C>G p.L417V | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.232); catalogued as COSV54152684, COSV54158503; called by muse, mutect2, varscan2
- PRKAA2 | c.496G>C p.D166H | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64806085; called by muse, mutect2, varscan2
- PRND | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.209); catalogued as COSV59897212; called by muse, mutect2, varscan2
- PSPH | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51908945; called by muse, mutect2, varscan2
- PTPN13 | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1229018561, COSV100365475; called by muse, mutect2, varscan2
- PTPRN2 | c.1049G>A p.G350D | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV67057583; called by muse, mutect2, varscan2
- PYGB | c.364G>T p.E122* | Nonsense Mutation (SNP) | VAF 11/24 reads (46%) | catalogued as COSV99405467; called by muse, mutect2, varscan2
- R3HDML | c.405G>A p.M135I | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV53837483; called by muse, mutect2, varscan2
- RASSF3 | c.162C>G p.I54M | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV51687230; called by muse, mutect2, varscan2
- RASSF8 | c.501G>C p.K167N | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV51452970, COSV51455009; called by muse, mutect2, varscan2
- RB1 | c.2361_2385del p.S788Pfs*14 | Frame Shift Del (DEL) | VAF 20/58 reads (34%) | catalogued as COSV57322822; called by mutect2, pindel
- RNF157 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.334); catalogued as COSV53947681; called by muse, mutect2, varscan2
- SAFB2 | c.1395C>G p.I465M | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV53044733; called by muse, mutect2, varscan2
- SBNO1 | c.818A>G p.D273G (on ENST00000420886; = p.D272G on NM_018183.5) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as rs1482371713, COSV57338990; called by muse, mutect2, varscan2
- SCLY | c.973G>C p.E325Q (on ENST00000651534; = p.E317Q on NM_016510.7) | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.887); catalogued as COSV54543735; called by muse, mutect2, varscan2
- SCNN1D | c.1468C>G p.Q490E (on ENST00000338555; = p.Q654E on NM_001130413.4) | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.149); catalogued as rs1454783036, COSV57644027; called by mutect2, varscan2
- SI | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52296473; called by muse, mutect2, varscan2
- SLC27A1 | c.1936C>G p.L646V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99393397, COSV99393652; called by muse, mutect2
- SLC27A3 | c.2059G>A p.E687K (on ENST00000271857; = p.E559K on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/201 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs547168142, COSV55163945; called by muse, mutect2, varscan2
- SLC9A1 | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 27/51 reads (53%) | catalogued as COSV99850055; called by muse, mutect2, varscan2
- SMC1A | c.337C>T p.Q113* | Nonsense Mutation (SNP) | VAF 22/79 reads (28%) | catalogued as COSV100447684; called by muse, mutect2, varscan2
- SNX5 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.677); catalogued as COSV66698479; called by muse, mutect2, varscan2
- SPON1 | c.2072G>A p.R691Q | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs782313864, COSV59958418; called by muse, mutect2, varscan2
- SRPK3 | c.1156G>A p.G386S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as rs782159346, COSV54209646; called by muse, mutect2, varscan2
- SYT1 | c.978G>T p.K326N | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54069149; called by mutect2, varscan2
- SYT5 | c.401G>C p.G134A | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.526); catalogued as COSV100845889, COSV62831149; called by muse, mutect2, varscan2
- TAB1 | c.1507G>T p.A503S | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as COSV53372846; called by muse, mutect2, varscan2
- TBX6 | c.1234C>T p.L412F | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.36); catalogued as COSV54223045; called by muse, mutect2
- TCF20 | c.2176C>T p.Q726* | Nonsense Mutation (SNP) | VAF 67/169 reads (40%) | catalogued as COSV100166958; called by muse, mutect2
- TICRR | c.2836G>C p.E946Q | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as COSV51545868; called by muse, mutect2, varscan2
- TJAP1 | c.1483G>C p.E495Q (on ENST00000372445 / NM_001146016.1; = p.E485Q on NM_080604.3) | Missense Mutation (SNP) | VAF 38/42 reads (90%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as COSV52503315; called by muse, mutect2, varscan2
- TJP2 | c.251G>C p.R84T | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55272386; called by muse, mutect2, varscan2
- TNFRSF11B | c.712G>C p.E238Q | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1331937056, COSV52073608; called by muse, mutect2, varscan2
- TNKS2 | c.382C>G p.L128V | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65416649; called by muse, mutect2, varscan2
- TNRC6A | c.1406C>T p.S469L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV59369073; called by muse, mutect2, varscan2
- TOE1 | c.810C>G p.F270L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV59156628; called by muse, mutect2, varscan2
- TRIM67 | c.919G>C p.E307Q | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.88); catalogued as rs1375736595, COSV100792211; called by muse, varscan2
- TSNAXIP1 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV54651693; called by muse, mutect2, varscan2
- TTLL5 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.105); catalogued as COSV54040520; called by muse, mutect2, varscan2
- TTPAL | c.968C>T p.S323L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.015); catalogued as COSV52828172; called by muse, mutect2, varscan2
- TULP4 | c.1424G>A p.R475Q | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs374889085; called by muse, mutect2, varscan2
- UBR4 | c.1349G>T p.R450L | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs757121959, CM156443, COSV64391411; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBTD2 | c.205G>C p.E69Q | Missense Mutation (SNP) | VAF 39/70 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs761409212, COSV67143875, COSV67143997, COSV67144172; called by muse, mutect2, varscan2
- XPO6 | c.2806G>A p.A936T | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as COSV58970423; called by muse, mutect2, varscan2
- ZBP1 | c.573G>C p.Q191H | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59064289; called by muse, mutect2, varscan2
- ZNF329 | c.409C>T p.H137Y | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as rs1278664580, COSV63773234; called by muse, mutect2, varscan2
- ZNF572 | c.29C>G p.S10* | Nonsense Mutation (SNP) | VAF 24/65 reads (37%) | catalogued as rs1344456481, COSV100074132, COSV60002117; called by muse, mutect2, varscan2
- ZNF592 | c.2804C>G p.S935* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100245806; called by muse, mutect2
- ZNF711 | c.557T>C p.I186T | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.245); catalogued as rs1190022222, COSV52158153; called by muse, mutect2, varscan2
- ZNF768 | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 18/68 reads (26%) | catalogued as COSV99411671; called by muse, mutect2, varscan2
- ZNF768 | c.63G>C p.M21I | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV53224670, COSV99411347; called by muse, mutect2, varscan2
- ZNF800 | c.1607G>T p.R536L | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56173920, COSV56179212; called by muse, mutect2, varscan2
- ZNF816 | c.758G>C p.R253T | Missense Mutation (SNP) | VAF 85/154 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.223); catalogued as COSV54412296; called by muse, mutect2, varscan2
- IRAG1 | c.1457C>T p.S486F | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2
- ZNF354B | c.550dup p.T184Nfs*6 | Frame Shift Ins (INS) | VAF 7/68 reads (10%) | called by mutect2, pindel, varscan2
- ADRA2C | c.516C>T p.I172= | Silent (SNP) | VAF 13/19 reads (68%) | catalogued as rs1185973370, COSV57468099; called by muse, mutect2, varscan2
- AK5 | c.840G>A p.Q280= (on ENST00000354567 / NM_174858.3; = p.Q254= on NM_012093.4) | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as rs777885275, COSV60971611, COSV60979708; called by muse, mutect2, varscan2
- ANO1 | c.1707C>A p.V569= | Silent (SNP) | VAF 676/732 reads (92%) | catalogued as rs1357294091, COSV60288405; called by muse, varscan2
- AP002512.3 | c.78C>T p.F26= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV56568185; called by muse, mutect2, varscan2
- ATP4A | c.2415C>T p.I805= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV52871137; called by muse, mutect2, varscan2
- ATRNL1 | c.2649G>A p.A883= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as rs149670730; called by muse, mutect2
- BMS1 | c.1704G>A p.L568= | Silent (SNP) | VAF 26/43 reads (60%) | catalogued as rs746799747, COSV65735203; called by muse, mutect2, varscan2
- BMX | c.1494G>A p.L498= | Silent (SNP) | VAF 123/285 reads (43%) | catalogued as COSV59593080; called by muse, mutect2, varscan2
- BPIFB4 | c.1566C>T p.D522= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs146042993; called by muse, varscan2
- C8orf74 | c.357C>T p.I119= | Silent (SNP) | VAF 81/110 reads (74%) | catalogued as rs138937646; called by muse, mutect2, varscan2
- CACNA1C | c.817C>T p.L273= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV59760736; called by mutect2, varscan2
- CBX7 | c.222G>A p.P74= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs754221134, COSV53358262; called by muse, mutect2, varscan2
- CHSY1 | c.1077T>C p.P359= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV54255556; called by muse, mutect2, varscan2
- CLTCL1 | c.237G>C p.V79= | Silent (SNP) | VAF 12/18 reads (67%) | catalogued as COSV54237685; called by muse, mutect2
- DENND2A | c.2304C>T p.V768= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV52057552; called by muse, mutect2, varscan2
- DHRS2 | c.396G>A p.G132= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV51633794; called by muse, mutect2, varscan2
- DOCK8 | c.1554C>T p.I518= | Silent (SNP) | VAF 35/47 reads (74%) | catalogued as COSV66635570; called by muse, mutect2, varscan2
- ESR1 | c.1275C>T p.F425= | Silent (SNP) | VAF 24/29 reads (83%) | catalogued as rs1179343201, COSV52798812; called by muse, mutect2, varscan2
- FAM111A | c.1410T>C p.H470= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV64655779; called by muse, mutect2, varscan2
- FAM83H | c.2793G>A p.P931= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as rs370284848, COSV62029824; called by muse, mutect2, varscan2
- FBF1 | c.3198G>A p.Q1066= (on ENST00000586717; = p.Q1081= on NM_001319193.1) | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV100045606; called by muse, mutect2, varscan2
- FLNA | c.4896C>T p.Y1632= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as rs782235294, COSV61048476; ClinVar: likely benign; called by muse, mutect2
- GOLGA4 | c.3672C>A p.T1224= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV62713270; called by muse, mutect2, varscan2
- GPAA1 | c.1029C>T p.F343= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV60156392; called by muse, mutect2, varscan2
- HHIPL2 | c.621C>G p.L207= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV58567241; called by muse, mutect2, varscan2
- ITLN1 | c.109C>T p.L37= | Silent (SNP) | VAF 38/83 reads (46%) | catalogued as COSV58276540; called by muse, mutect2, varscan2
- KCNN3 | c.978C>T p.S326= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as rs1315413625, COSV55224839; called by muse, mutect2, varscan2
- KDELR3 | c.387G>A p.V129= | Silent (SNP) | VAF 52/121 reads (43%) | catalogued as COSV53249446; called by muse, mutect2, varscan2
- KRTAP13-3 | c.279G>C p.L93= | Silent (SNP) | VAF 13/20 reads (65%) | catalogued as COSV61880094; called by muse, mutect2, varscan2
- LRP12 | c.1656G>A p.L552= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as COSV52633651; called by muse, mutect2, varscan2
- LRRC4B | c.345G>A p.L115= | Silent (SNP) | VAF 21/37 reads (57%) | catalogued as rs1353295549, COSV65350654; called by muse, mutect2, varscan2
- MTCH2 | c.42C>T p.L14= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as rs1182404518, COSV56768561; called by muse, mutect2, varscan2
- MYO1F | c.1086C>T p.F362= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs755593569, COSV57795190; called by muse, mutect2, varscan2
- NFE2L1 | c.1011C>T p.Y337= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs1567755384, COSV62583709; called by muse, mutect2, varscan2
- NLRP7 | c.1989C>G p.L663= | Silent (SNP) | VAF 41/103 reads (40%) | catalogued as COSV60180479; called by muse, mutect2, varscan2
- NXN | c.1119C>T p.A373= | Silent (SNP) | VAF 37/48 reads (77%) | catalogued as rs547654184, COSV61098321; called by muse, mutect2, varscan2
- OPHN1 | c.699G>A p.Q233= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV100830780; called by muse, mutect2
- OR4K1 | c.867G>C p.L289= | Silent (SNP) | VAF 31/61 reads (51%) | catalogued as COSV53462083; called by muse, mutect2, varscan2
- PGGHG | c.1827G>A p.V609= | Silent (SNP) | VAF 28/43 reads (65%) | catalogued as COSV66888548; called by muse, mutect2, varscan2
- PHC1 | c.2325G>A p.E775= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs1002305357, COSV101418710; called by muse, mutect2, varscan2
- RP1L1 | c.822G>A p.L274= | Silent (SNP) | VAF 33/45 reads (73%) | catalogued as rs1214754683, COSV66759196; called by muse, mutect2, varscan2
- RTN4 | c.2415C>T p.L805= | Silent (SNP) | VAF 57/81 reads (70%) | catalogued as COSV58272810; called by muse, mutect2, varscan2
- SACS | c.9165C>G p.V3055= | Silent (SNP) | VAF 15/27 reads (56%) | catalogued as COSV66545738; called by muse, mutect2, varscan2
- SCN10A | c.2031G>A p.V677= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as COSV71862513; called by muse, mutect2, varscan2
- SH3PXD2B | c.2259G>A p.Q753= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV100288554, COSV61129457; called by muse, mutect2, varscan2
- SLC36A3 | c.1299C>T p.I433= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as COSV58857956; called by muse, mutect2, varscan2
- SLC45A1 | c.1755C>T p.F585= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs1177463718, COSV57096375, COSV57097956; called by muse, mutect2, varscan2
- SLC7A7 | c.375C>T p.L125= | Silent (SNP) | VAF 38/113 reads (34%) | catalogued as rs199724860, COSV53542244; called by muse, mutect2, varscan2
- SSU72 | c.267G>A p.K89= | Silent (SNP) | VAF 77/151 reads (51%) | catalogued as COSV52218697; called by muse, mutect2, varscan2
- SYNE2 | c.726G>C p.L242= | Silent (SNP) | VAF 42/102 reads (41%) | catalogued as COSV58362356; called by muse, mutect2, varscan2
- TANC1 | c.4824C>T p.R1608= | Silent (SNP) | VAF 23/28 reads (82%) | catalogued as rs1298413067, COSV55095040; called by muse, mutect2, varscan2
- TENM3 | c.4542G>A p.A1514= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs758597377, COSV69299947; called by muse, mutect2, varscan2
- TH | c.1389C>T p.F463= (on ENST00000381178 / NM_199292.3; = p.F432= on NM_000360.4) | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs760210103, COSV51746974, COSV51747241; called by muse, mutect2, varscan2
- TJP3 | c.2088C>G p.V696= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV53665125, COSV53665624; called by muse, mutect2, varscan2
- TMOD2 | c.441A>T p.P147= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV51046549; called by muse, mutect2, varscan2
- TMPRSS11F | c.1206C>T p.Y402= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as rs761843293, COSV62464616; called by muse, mutect2, varscan2
- TSKU | c.834G>A p.L278= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV60752704; called by muse, mutect2, varscan2
- VKORC1 | c.381G>A p.V127= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as COSV54926240; called by muse, mutect2, varscan2
- WDR35 | c.3183C>T p.I1061= (on ENST00000345530 / NM_001006657.2; = p.I1050= on NM_020779.4) | Silent (SNP) | VAF 55/69 reads (80%) | catalogued as COSV55606209; called by muse, mutect2, varscan2
- ZKSCAN5 | c.813G>A p.Q271= | Silent (SNP) | VAF 39/106 reads (37%) | catalogued as COSV58744273; called by muse, mutect2, varscan2
- ZNF676 | c.154C>T p.L52= (on ENST00000650058; = p.L20= on NM_001001411.3) | Silent (SNP) | VAF 35/73 reads (48%) | catalogued as rs201235589, COSV68092257, COSV68093380; called by muse, mutect2, varscan2
- ZNFX1 | c.3000G>A p.P1000= | Silent (SNP) | VAF 91/216 reads (42%) | catalogued as rs773494872, COSV65576639; called by muse, mutect2, varscan2
- ZSCAN29 | c.1162C>T p.L388= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV53020950; called by muse, mutect2, varscan2
- ITGA3 | c.*94C>T | 3'UTR (SNP) | VAF 22/104 reads (21%) | catalogued as COSV50315942, COSV50334069; called by muse, mutect2, varscan2
- LINC00482 | n.795G>A | RNA (SNP) | VAF 4/9 reads (44%) | catalogued as rs1404928003; called by muse, mutect2, varscan2
- MIR509-1 | n.76G>C | RNA (SNP) | VAF 69/193 reads (36%) | called by muse, mutect2, varscan2
- OR52E4 | c.-2G>C | 5'UTR (SNP) | VAF 10/72 reads (14%) | catalogued as COSV100389342, COSV100389372, COSV100389379; called by muse, mutect2, varscan2
- PLEC | c.523+5523G>T | Intron (SNP) | VAF 5/18 reads (28%) | catalogued as rs1554731123, COSV100512158, COSV59683956; called by muse, mutect2, varscan2
- PML | c.1710+745G>C | Intron (SNP) | VAF 44/90 reads (49%) | catalogued as rs1294883560, COSV51452685; called by muse, mutect2, varscan2
- SNORD115-44 | n.67G>C | RNA (SNP) | VAF 53/238 reads (22%) | called by muse, mutect2, varscan2
- XIST | n.9987C>T | RNA (SNP) | VAF 15/37 reads (41%) | called by muse, mutect2, varscan2
